Somatic mutation profile of tumor specimen RC-B5DA-TBP1-A (aliquot RC-B5DA-TBP1-A-1-0-D-A93N-47) from RC case RC-B5DA, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: T-cell large granular lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 37.0 years (13,520 days).
Specimen RC-B5DA-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25f5977d-ae6b-4789-bfa7-33cc311faa68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B5DA-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B5DA-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52de2d89-0c52-42f9-b133-e558e64b8e35

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCFL | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342376600; called by muse, mutect2, varscan2
- GABRA5 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.903); catalogued as rs1225748704, COSV100165441, COSV59478114; called by muse, varscan2
- IL6ST | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs768979387, COSV100410952, COSV61142964; called by muse, varscan2
- ITSN1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV101180470; called by muse, mutect2, varscan2
- LRRC1 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs373006710; called by muse, mutect2, varscan2
- POF1B | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 67/98 reads (68%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.827); catalogued as rs762587537; called by muse, mutect2, varscan2
- STAT3 | c.1919A>T p.Y640F | Missense Mutation (SNP) | VAF 112/161 reads (70%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); catalogued as rs769031989, COSV52882807; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by mutect2, varscan2
- TRPC5 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 71/114 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1222929602, COSV53290183; called by muse, mutect2, varscan2
- TRPM8 | c.2063G>T p.R688L | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV61221585; called by muse, varscan2
- ADGRG5 | c.146T>A p.L49H | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CHST7 | c.424T>C p.Y142H | Missense Mutation (SNP) | VAF 66/106 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CMYA5 | c.388A>G p.K130E | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, varscan2
- KLHL20 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PARM1 | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPS7 | c.361A>C p.T121P | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SEC23B | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- TP53AIP1 | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 54/183 reads (30%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.10986C>A p.I3662= | Silent (SNP) | VAF 58/236 reads (25%) | called by muse, mutect2, varscan2
- GABRA6 | c.1135T>C p.L379= | Silent (SNP) | VAF 44/178 reads (25%) | catalogued as rs1375011353; called by muse, mutect2, varscan2
- MRTFB | c.264G>A p.L88= | Silent (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- RPRD1B | c.357C>T p.G119= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as rs1435333633; called by muse, mutect2, varscan2
- SLC26A1 | c.1287G>A p.A429= | Silent (SNP) | VAF 75/210 reads (36%) | catalogued as rs747095997; called by muse, varscan2
- SLC66A1 | c.192C>A p.G64= | Silent (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- DCLK1 | c.1035+3730A>T | Intron (SNP) | VAF 59/189 reads (31%) | called by muse, mutect2, varscan2
- LRGUK | c.1843+7527A>C | Intron (SNP) | VAF 65/232 reads (28%) | called by muse, mutect2, varscan2
